Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90Y, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A90Y-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD-O-3
Carcinoma, embryonal
8070/3
Site @ Testis NOS
C62.9
JW 3/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

1. "Left testis":

- . Mixed germ cell tumor, composed of embryonal carcinoma (95%) and yolk sac tumor (5%), measuring 4.5 cm.
- . Presence of intratubular embryonal carcinoma.
- . Multiple foci of angiolymphatic vascular invasion.
- . Rete testis and tunica albuginea infiltrated by neoplasia.
- . Base of spermatic cord focally infiltrated by neoplasia.
- . Presence of intravascular neoplastic embolus at the margin of spermatic cord.
- . Epididymis uninvolved by neoplasia.
- . Tunica vaginalis uninvolved by neoplasia.

Source: NCI Genomic Data Commons file afffff7c-f599-4ceb-a245-e3dfa304937b (TCGA-YU-A90Y.454A119C-95C4-44DB-BF96-0026F21CF1ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).